Somatic mutation profile of tumor specimen MBCProject_0203_T1B_WES (aliquot MBCProject_0203_T1B_WES_1) from CMI case MBCProject_0203, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.4 years (17,691 days).
Specimen MBCProject_0203_T1B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02363064-21cd-4f31-8dd1-098810bb4ab2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0203_SALIVA (Saliva), aliquot MBCProject_0203_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56540e13-c145-443b-8926-1d4deb2568be

The open-access MAF lists 155 somatic variants for this specimen: 112 protein-altering or splice-affecting, 19 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 19, Intron 11, In Frame Del 5, Splice Site 5, 3'UTR 5, Nonsense Mutation 4, Frame Shift Del 4, 5'UTR 3, 3'Flank 3, Frame Shift Ins 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3227T>A p.I1076K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1356591712, COSV99684907; called by muse, mutect2, varscan2
- AMER1 | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.548); catalogued as COSV57658675; called by mutect2, varscan2
- AOC3 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs151291423; called by muse, mutect2, varscan2
- ASTN1 | c.3807C>G p.S1269R | Missense Mutation (SNP) | VAF 141/470 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as COSV100706916; called by muse, mutect2, varscan2
- CBY2 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 75/395 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV60118086; called by muse, mutect2, varscan2
- CFHR4 | c.1368G>C p.K456N (on ENST00000367416 / NM_001201551.2; = p.K210N on NM_006684.5) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV52223932; called by mutect2, varscan2
- CHERP | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as rs779384365, COSV52226935; called by muse, mutect2, varscan2
- CHST2 | c.1226C>G p.A409G | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs769639046; called by muse, mutect2, varscan2
- DNAI4 | c.1778G>T p.W593L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755382003; called by mutect2, varscan2
- DOC2A | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58751371; called by muse, mutect2, varscan2
- FAM20C | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 65/480 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.018); catalogued as rs1245703345; called by muse, mutect2, varscan2
- GALNT12 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 46/452 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs536814570; called by muse, mutect2, varscan2
- HUWE1 | c.3979G>T p.D1327Y | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53339081; called by muse, mutect2, varscan2
- LINGO4 | c.557C>A p.T186N | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.53); catalogued as COSV100562014; called by muse, varscan2
- MAP4K1 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs770505238; called by muse, mutect2, varscan2
- NR6A1 | c.563A>T p.N188I (on ENST00000487099 / NM_033334.4; = p.N184I on NM_001489.5) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV60633434; called by muse, mutect2, varscan2
- OR10A2 | c.565G>T p.G189* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as rs758895114, COSV100224941; called by muse, mutect2, varscan2
- OR7A10 | c.533dup p.C179Lfs*2 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | catalogued as rs758596389; called by pindel, varscan2
- PCDHAC1 | c.1511G>A p.S504N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as rs1554205862; called by muse, mutect2, varscan2
- PLEKHG4B | c.3383T>G p.F1128C (on ENST00000283426; = p.F1484C on NM_052909.5) | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV52054960; called by muse, mutect2
- POU6F2 | c.1130C>A p.T377K | Missense Mutation (SNP) | VAF 48/410 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs1472321299; called by muse, mutect2, varscan2
- PRR30 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1382257449; called by muse, mutect2, varscan2
- SDK2 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 32/445 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66183260; called by muse, mutect2
- SELENOV | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 51/459 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1462075637; called by muse, mutect2, varscan2
- SERPINB11 | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV101236322; called by muse, mutect2, varscan2
- SPG7 | c.1903G>A p.E635K (on ENST00000268704; = p.E642K on NM_003119.4) | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1202120338, COSV51954483; called by muse, mutect2, varscan2
- SRRM4 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.02); catalogued as rs770735386; called by muse, mutect2, varscan2
- TCP10L | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs746268293; called by muse, varscan2
- TGFB2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745960678; called by muse, mutect2, varscan2
- TGM2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 124/428 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as rs577909675; called by muse, mutect2, varscan2
- A2ML1 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ABCC12 | c.3715-17_3744del p.X1239_splice | Splice Site (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel
- ANK3 | c.6587C>A p.P2196H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO4 | c.2589C>A p.D863E (on ENST00000392977 / NM_001286615.2; = p.D828E on NM_178826.4) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, varscan2
- ARHGAP42 | c.755G>T p.R252M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ARHGEF11 | c.2779A>T p.T927S | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ATP2B4 | c.148_162delinsCTA p.G50_N53del | In Frame Del (DEL) | VAF 36/113 reads (32%) | called by pindel, varscan2*
- BDNF | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CALCR | c.588G>T p.R196S (on ENST00000649521 / NM_001164737.2; = p.R180S on NM_001742.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDYL | c.158G>C p.S53T | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL16A1 | c.506A>T p.H169L | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CRYBA4 | c.300+2_300+19del p.X100_splice | Splice Site (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- DDX31 | c.2372A>G p.Y791C | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- DDX5 | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- DNAH3 | c.4662G>A p.M1554I | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH5 | c.2428A>T p.I810F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DNAJC18 | c.312_324del p.K104Nfs*19 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel
- DNAJC3 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DOK5 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- EMC1 | c.1038C>G p.S346R | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- EMILIN1 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- EPS8L2 | c.984+2T>C p.X328_splice | Splice Site (SNP) | VAF 36/300 reads (12%) | called by muse, mutect2, varscan2
- FAM122A | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FBXO41 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FOXJ1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- FSD1 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FUZ | c.371_372insTTT p.L124dup | In Frame Ins (INS) | VAF 40/350 reads (11%) | called by mutect2, pindel, varscan2
- GCM2 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 194/866 reads (22%) | called by muse, mutect2, varscan2
- GH1 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 34/580 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- GRIN1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 63/341 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- GRK2 | c.808A>C p.I270L | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- HTR3A | c.764T>G p.F255C | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INPP1 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IQCF1 | c.171+1_171+6del p.X57_splice | Splice Site (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- IQCF5 | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 85/150 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM6B | c.4901del p.F1634Sfs*36 (on ENST00000448097 / NM_001348716.1; = p.F1634Sfs*4 on NM_001080424.2) | Frame Shift Del (DEL) | VAF 66/307 reads (21%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.8012A>G p.K2671R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIAA1549L | c.3911C>T p.P1304L (on ENST00000321505; = p.P1601L on NM_012194.3) | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIF1A | c.4459A>T p.S1487C (on ENST00000320389 / NM_001379639.1; = p.S1479C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/359 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRN2 | c.1627C>A p.L543I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MALT1 | c.2305A>T p.S769C | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.43); called by muse, mutect2
- MAOA | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MAP1A | c.7006_7017del p.H2336_C2339del | In Frame Del (DEL) | VAF 39/206 reads (19%) | called by mutect2, pindel, varscan2
- MAPK8IP1 | c.607del p.X203_splice | Splice Site (DEL) | VAF 34/272 reads (13%) | called by mutect2, pindel, varscan2
- MLLT6 | c.2975_3013del p.P992_L1004del | In Frame Del (DEL) | VAF 28/162 reads (17%) | called by mutect2, pindel
- MRPL11 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by mutect2, varscan2
- MRPL17 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MUC16 | c.34895C>A p.T11632N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.3359_3376del p.I1120_T1125del | In Frame Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- MYH7 | c.1074C>A p.H358Q | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- MYT1L | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- OXCT1 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- OXCT1 | c.484G>T p.G162W | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITPNM2 | c.1208_1210del p.Q403del | In Frame Del (DEL) | VAF 42/259 reads (16%) | called by pindel, varscan2
- PLCG2 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PLXNA1 | c.1172A>C p.K391T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- PRDM15 | c.871dup p.S291Kfs*54 | Frame Shift Ins (INS) | VAF 34/142 reads (24%) | called by mutect2, pindel
- PSG4 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- PWWP2B | c.172_179del p.D58Pfs*119 | Frame Shift Del (DEL) | VAF 38/251 reads (15%) | called by mutect2, pindel, varscan2
- QRICH2 | c.80A>T p.D27V | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2
- RABGAP1L | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by mutect2, varscan2
- RHBDF2 | c.1526T>C p.I509T | Missense Mutation (SNP) | VAF 52/560 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2
- RPGR | c.2857A>G p.I953V (on ENST00000339363 / NM_001367249.1; = p.I748V on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINA6 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC1A4 | c.329T>A p.L110H | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC22A31 | c.237del p.D81Tfs*13 | Frame Shift Del (DEL) | VAF 38/220 reads (17%) | called by pindel, varscan2
- SLC35A1 | c.988T>G p.S330A | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SLCO5A1 | c.1030A>T p.I344F | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SPRYD3 | c.731A>C p.D244A | Missense Mutation (SNP) | VAF 47/393 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- STAB2 | c.3518C>T p.T1173I | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1L | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- TFPI | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | called by mutect2, varscan2
- TIGD5 | c.1660C>G p.P554A | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPTE | c.1546G>T p.D516Y (on ENST00000618007 / NM_199261.4; = p.D498Y on NM_199259.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- WDFY4 | c.4906C>A p.H1636N | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- WNT6 | c.1037G>C p.W346S | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZAN | c.3725C>G p.A1242G | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ZIC4 | c.956T>G p.V319G | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF217 | c.1884G>T p.K628N | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF235 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZSCAN1 | c.757A>T p.R253W | Missense Mutation (SNP) | VAF 57/422 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- ZSCAN22 | c.206A>T p.H69L | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACHD1 | c.243A>G p.G81= | Silent (SNP) | VAF 5/31 reads (16%) | called by mutect2, varscan2
- CACNA1B | c.1695C>A p.A565= | Silent (SNP) | VAF 72/196 reads (37%) | called by muse, mutect2, varscan2
- CADPS | c.576T>A p.R192= | Silent (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2
- COL20A1 | c.1293G>A p.T431= | Silent (SNP) | VAF 229/519 reads (44%) | catalogued as rs780583500, COSV58918554; called by muse, mutect2, varscan2
- DGKG | c.1632G>A p.L544= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99403308; called by mutect2, varscan2
- ERCC1 | c.483G>A p.G161= | Silent (SNP) | VAF 95/585 reads (16%) | catalogued as rs371397437; called by muse, mutect2, varscan2
- GAL3ST3 | c.924C>T p.H308= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs1222376422; called by muse, mutect2, varscan2
- INPP4A | c.1336A>C p.R446= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- ITGA9 | c.519C>T p.G173= | Silent (SNP) | VAF 58/268 reads (22%) | called by muse, mutect2, varscan2
- KCND3 | c.1749G>A p.Q583= | Silent (SNP) | VAF 63/277 reads (23%) | called by muse, mutect2, varscan2
- KLHDC8A | c.727C>A p.R243= | Silent (SNP) | VAF 30/324 reads (9%) | called by muse, mutect2
- MAP4K4 | c.516T>C p.F172= | Silent (SNP) | VAF 53/162 reads (33%) | catalogued as rs1268907751; called by muse, mutect2, varscan2
- MUC1 | c.3705C>G p.P1235= (on ENST00000611571 / NM_001371720.1; = p.P246= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2
- MUC5B | c.828A>T p.A276= | Silent (SNP) | VAF 46/561 reads (8%) | called by muse, mutect2
- PDE4DIP | c.3024C>T p.H1008= | Silent (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- PRDM5 | c.1683T>C p.D561= | Silent (SNP) | VAF 32/281 reads (11%) | catalogued as rs1275093218; called by muse, varscan2
- RAB11FIP3 | c.1422G>A p.L474= | Silent (SNP) | VAF 24/377 reads (6%) | catalogued as COSV51933771, COSV99240493; called by muse, mutect2
- RASGRP4 | c.645G>C p.R215= | Silent (SNP) | VAF 45/107 reads (42%) | called by muse, mutect2, varscan2
- TRAV6 | c.309C>G p.V103= | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, varscan2
- AC090151.1 | chr8:54701643 A>T | 3'Flank (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- AC106038.2 | chr8:90703433 del AGGTA | 3'Flank (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- ACBD5 | chr10:27196135 A>G | 3'Flank (SNP) | VAF 10/60 reads (17%) | called by mutect2, varscan2
- AP3D1 | c.2601+746C>A | Intron (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- CEACAM1 | c.1247-2540A>G | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as rs1264907378; called by muse, varscan2
- CFTR | c.-34C>T | 5'UTR (SNP) | VAF 53/220 reads (24%) | catalogued as rs756314710, CR118489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRIM1 | c.2429-5437C>T | Intron (SNP) | VAF 39/70 reads (56%) | called by muse, mutect2, varscan2
- DAPK1 | c.1626+45G>T | Intron (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- DERL1 | c.-1G>T | 5'UTR (SNP) | VAF 19/232 reads (8%) | called by muse, mutect2
- GPATCH8 | c.*1799A>G | 3'UTR (SNP) | VAF 32/224 reads (14%) | called by muse, varscan2
- KNG1 | c.*1395_*1427del | 3'UTR (DEL) | VAF 20/250 reads (8%) | called by mutect2, pindel
- LITAF | c.*861G>C | 3'UTR (SNP) | VAF 14/142 reads (10%) | catalogued as rs1329756404; called by muse, mutect2
- LTB | c.208+43G>C | Intron (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2, varscan2
- NECAP2 | c.489+959C>G | Intron (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- NKX6-3 | c.*42G>T | 3'UTR (SNP) | VAF 40/928 reads (4%) | called by muse, mutect2
- PCSK5 | c.2626+3607G>T | Intron (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- PLEKHM1P1 | n.1581G>T | RNA (SNP) | VAF 63/1160 reads (5%) | called by muse, mutect2
- POLR2H | c.-53C>G | 5'UTR (SNP) | VAF 167/564 reads (30%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 30/483 reads (6%) | catalogued as rs910081914; called by muse, mutect2
- SLC4A8 | c.2172+4996A>G | Intron (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- SMARCD2 | c.*1C>T | 3'UTR (SNP) | VAF 28/416 reads (7%) | called by muse, mutect2
- STXBP2 | c.88-22_88-19del | Intron (DEL) | VAF 97/255 reads (38%) | called by mutect2, pindel, varscan2
- TK1 | chr17:78187097 A>G | 5'Flank (SNP) | VAF 28/346 reads (8%) | catalogued as rs1216718360; called by muse, mutect2
- YIPF3 | c.395+329G>T | Intron (SNP) | VAF 27/373 reads (7%) | catalogued as rs1383044718, COSV104411955; called by muse, mutect2
